Surgical pathology report (de-identified scan), TCGA case TCGA-K7-A6G5, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K7-A6G5-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. GALLBLADDER-
- B. RIGHT LOBE OF LIVER FS-
- C. RIGHT LOBE OF LIVER NFS-

FINAL DIAGNOSIS:

- A. GALLBLADDER-
GALLBLADDER WITH MINIMAL CHRONIC INFLAMMATION.
ONE CYSTIC LYMPH NODE WITH LIPOGRANULOMAS.

- B. RIGHT LOBE OF LIVER FS-
SEE PART "C".

- C. RIGHT LOBE OF LIVER NFS-
WELL TO MODERATELY DIFFERENTIATED HEPATOCELLULAR CARCINOMA,
SOLITARY, WITH FOCAL INFARCTION, CONFINED TO LIVER.

HISTOLOGIC GRADE: 1-2/4.

TUMOR LOCATION: RIGHT LOBE OF LIVER.

TUMOR SIZE: 2.2 CM (GROSSLY).

LYMPH-VASCULAR INVASION:

MACROSCOPIC VENOUS INVASION: NOT PRESENT.

MICROSCOPIC SMALL VESSEL/LYMPHATIC INVASION: NOT PRESENT.

TNM STAGE: pT1, pN0, pMX.

ICD O-3
Carcinoma, hepatocellular
8170/3
Site Liver C22.0
W 7/5/13

Prepared for

[page 2 of 4]
LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0

NUMBER EXAMINED: 2 *

* including one cystic lymph node

SATELLITE LESIONS: NOT PRESENT.

SPECIMEN TYPE: RIGHT LOBECTOMY.

SPECIMEN SIZE: 15.0 x 15.0 x 7.0 cm

UNOS HCC STAGE: STAGE 2.

(stage 1: unifocal < 2 cm; stage 2: unifocal < 5 cm or 2-3 foci, < 3cm).

TIPS: NO

MARGINS: UNINVOLVED, THE TUMOR EXTENDS TO 0.5 CM FROM CLOSEST PARENCHYMAL RESECTION MARGIN.

ADJACENT LIVER WITH MODERATE STEATOSIS, MILD PORTAL INFLAMMATION WITH MINIMAL PERIPORTAL AND LOBULAR EXTENSION CONSISTENT WITH CHRONIC HEPATITIS, GRADE 1/4 AND STAGE 1-2/4.

CIRRHOSIS/FIBROSIS: NOT PRESENT.

MINIMAL STAINABLE IRON NOTED IN HEPATOCYTES.

Comment

Trichrome, reticulin, and iron stains examined.

By immunohistochemistry, the tumor is positive for Heppar and glypican. CEA polyclonal shows a canalicular pattern. The morphology and immunoprofile supports the above diagnosis.

Appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

Signature

(Case signed

Signed Others

Frozen Section

A. RIGHT LOBE OF LIVER: 2.2 CM WELL-DEMARCATED, FIRM, SOLID NODULE.

FS: HEPATOCELLULAR CARCINOMA (? ARISING IN FOCAL NODULAR

Prepared for

[page 3 of 4]
HYPERPLASIA). NO CHOLANGIOCARCINOMA SEEN ON FS.

Frozen section performed by

(Frozen Section Signed

Case Clinical Information
HEPATOCELLULAR CARCINOMA HCV

Gross Description

A. Received in formalin labeled with the patient's name and "gallbladder" is an intact gallbladder measuring 10 cm in length, 2.8 cm in diameter, revealing a 1.5 cm cystic duct. The gallbladder contains dark green bile of average viscosity and demonstrates a velvety, dark green mucosa. The gallbladder measures 1.5 mm thick. No gallstones or focal lesions. Shave from the cystic duct resection margin cross sectioned mid gallbladder body sampled, A1.

B. Received in formalin labeled with the patient's name and "right lobe of liver FS" is a firm, rounded, pale tan tissue measuring 2.5 x 2 x 0.2 cm thick. The specimen is totally submitted in B1.

C. Received in formalin labeled with the patient's name and "right lobe of liver NTS" is a portion of liver consistent with right lobe, measuring 15 cm medial to lateral x 15 cm superior to inferior x 7 cm anterior to posterior. The parenchymal resection margin measures 14 x 6.5 cm and has been partially previously incised. The resection margin is inked black at this time. On sectioning, the hepatic parenchyma is uniformly partially fixed pale brown without gross nodularity or bile duct distention. The prior sections perpendicular to the inked parenchymal margin expose a multinodular, firm, solid, white tumor, originally measuring 2.2 cm in greatest dimension. The tumor is adjacent to the hepatic capsule and separated from the focally disrupted, inked parenchymal margin by a minimum 0.5 cm of grossly benign hepatic parenchyma. Photos obtained. Section code: C1-C4=sections perpendicular to the parenchymal resection margin in the area of apparent vascular and biliary structures; C5=representative section of grossly unremarkable hepatic parenchyma remote from tumor; C6-C12=extensive sampling of tumor in relationship to inked parenchymal margin to include entire tumor.

Physicians

Prepared for

[page 4 of 4]
Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.5
H&E X1 TRICHROME FE RETIC
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1 GLYP-3 HEP PAR CEA POLYCLONAL
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
C. AA ROUTINE H&E X1 BLOCK.8
H&E X1
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1
C. AA ROUTINE H&E X1 BLOCK.12
H&E X1

Prepared for

Source: NCI Genomic Data Commons file dec606bd-8a3f-4e65-809e-bf225799765d (TCGA-K7-A6G5.BA14915C-0D72-4A11-AAFA-DD51FC6309B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).